Somatic mutation profile of tumor specimen 0DQKYL from CCDI case PBCELV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Malignant peripheral nerve sheath tumor with rhabdomyoblastic differentiation; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.9 years (5,802 days).
Specimen 0DQKYL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 112b0397-ca29-466a-a9eb-625f474eaa57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQKZI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b71d3b64-13ae-45b8-9dbb-b49b10c506d2

The open-access MAF lists 30 somatic variants for this specimen: 16 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 11, Intron 2, Splice Site 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2534G>C p.G845A | Missense Mutation (SNP) | VAF 114/2524 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.776); catalogued as rs749391307; called by muse, mutect2
- ARHGEF11 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 223/449 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs755424336; called by muse, mutect2, varscan2
- BRCA1 | c.4825G>A p.E1609K | Missense Mutation (SNP) | VAF 425/1284 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV58801577; called by muse, mutect2, varscan2
- BRCA1 | c.4678G>A p.G1560R | Missense Mutation (SNP) | VAF 463/1339 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as CM126107; called by muse, mutect2, varscan2
- CACNA2D3 | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 467/1296 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs777014208; called by muse, mutect2, varscan2
- GZMB | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 401/991 reads (40%) | catalogued as rs756531107; called by muse, mutect2, varscan2
- MXRA5 | c.8215C>T p.P2739S | Missense Mutation (SNP) | VAF 213/955 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs756029305; called by muse, mutect2, varscan2
- OR10AG1 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 455/1291 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV56632040; called by muse, mutect2, varscan2
- SIGLEC5 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 310/773 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs764295708, COSV55781034; called by muse, mutect2, varscan2
- SUZ12 | c.823+2T>C p.X275_splice | Splice Site (SNP) | VAF 434/605 reads (72%) | catalogued as COSV59498656; called by mutect2, varscan2
- ARHGDIA | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 189/1975 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- C16orf71 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- CCR4 | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 70/1104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDC25A | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 66/1054 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2
- PRR32 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 104/842 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM4 | c.3462-1G>C p.X1154_splice | Splice Site (SNP) | VAF 27/559 reads (5%) | called by muse, mutect2
- CCDC96 | c.1200C>A p.T400= | Silent (SNP) | VAF 94/906 reads (10%) | called by muse, mutect2
- GLRA4 | c.795C>A p.P265= | Silent (SNP) | VAF 66/559 reads (12%) | catalogued as COSV65457136; called by muse, mutect2, varscan2
- HTRA3 | c.693C>T p.I231= | Silent (SNP) | VAF 460/1215 reads (38%) | called by muse, mutect2
- ITPR2 | c.5094A>T p.I1698= | Silent (SNP) | VAF 36/881 reads (4%) | called by muse, mutect2
- KAT5 | c.885C>A p.R295= | Silent (SNP) | VAF 301/1275 reads (24%) | catalogued as COSV57729787; called by muse, mutect2, varscan2
- LYVE1 | c.33C>G p.L11= | Silent (SNP) | VAF 315/736 reads (43%) | called by muse, mutect2, varscan2
- NSF | c.1515C>T p.N505= | Silent (SNP) | VAF 164/931 reads (18%) | catalogued as rs756947942, COSV99833773; called by muse, mutect2, varscan2
- PCDH7 | c.1773C>T p.I591= | Silent (SNP) | VAF 72/820 reads (9%) | called by muse, mutect2
- SNX4 | c.471T>G p.G157= | Silent (SNP) | VAF 90/1658 reads (5%) | called by muse, mutect2
- VSX1 | c.99C>T p.I33= | Silent (SNP) | VAF 22/453 reads (5%) | catalogued as COSV65021435; called by muse, mutect2
- WDR19 | c.1110C>T p.V370= | Silent (SNP) | VAF 90/1093 reads (8%) | catalogued as COSV56467927; called by muse, mutect2
- DECR1 | c.885+55G>C | Intron (SNP) | VAF 50/728 reads (7%) | catalogued as rs1340142965; called by muse, mutect2
- PRDM12 | c.*70_*71delinsA | 3'UTR (DEL) | VAF 5/32 reads (16%) | called by pindel, varscan2*
- SNF8 | c.245-9G>A | Intron (SNP) | VAF 81/1703 reads (5%) | called by muse, mutect2
